Gene-level copy-number profile of tumor specimen ALCH-B2M5-TTP1-A from ALCHEMIST case ALCH-B2M5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.9 years (25,529 days).
Specimen ALCH-B2M5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e512f25a-0014-45e6-848b-bf10f9154a12.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2M5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/50c8dc22-737a-4275-8beb-e7798d4ee6b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 104; copy number 1: 4,265; copy number 2: 28,771; copy number 3: 13,286; copy number 4: 10,581; copy number 5: 1,031; copy number 6: 274; copy number 7: 159; copy number 8: 96; copy number 9: 25; copy number 10: 57; copy number 11: 73; copy number 12: 95; copy number 14: 7; copy number 15: 31; copy number 17: 2; copy number 19: 9; copy number 21: 11; copy number 22: 5; copy number 26: 2; copy number 27: 2; copy number 88: 1; copy number 89: 1.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,848,318–9,850,154, 1 gene (within-gene range 0–2): AL357140.1.
- chr1:16,035,178–16,040,029, 1 gene: AL355994.2.
- chr1:143,541,768–144,401,355, 31 genes: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4.
- chr2:153,158,938–153,201,762, 2 genes: ATP5PBP4, AC011901.1.
- chr2:240,886,048–240,993,311, 4 genes (within-gene range 0–2): MAB21L4, CROCC2, UICLM, AC104809.1.
- chr3:11,607,184–11,610,748, 1 gene (within-gene range 0–2): AC022001.2.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–2): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:50,396,192–51,167,647, 14 genes: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P.
- chr9:6,704,270–6,707,780, 1 gene: LINC02851.
- chr11:787,115–798,281, 2 genes (within-gene range 0–2): CEND1, SLC25A22.
- chr15:20,890,206–20,901,609, 3 genes: AC012414.5, AC037471.2, ZNF519P2.
- chr15:20,940,252–21,020,851, 8 genes (within-gene range 0–4): MIR5701-1, OR11J5P, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C.
- chr15:25,169,337–25,170,804, 2 genes (within-gene range 0–2): DMAC1P1, SNORD115-1.
- chr15:25,180,497–25,191,497, 7 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12.
- chr15:40,035,690–40,076,539, 2 genes (within-gene range 0–1): SRP14, SRP14-AS1.
- chr16:69,976,388–69,996,188, 1 gene (within-gene range 0–2): NPIPB14P.
- chr17:49,939,122–49,939,819, 1 gene: AC027801.3.
- chr22:50,245,183–50,261,716, 2 genes: HDAC10, MAPK12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,881 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:257,864–522,928, 10 genes, copy number 7 (within-gene range 3–7): AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:119,748,002–143,386,122, 50 genes, copy number 5: HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691, AC242852.1, AC242852.2.
- chr2:179,101,678–193,277,614, 154 genes, copy number 6–27 (broad region; genes not listed).
- chr3:99,215,224–100,748,964, 23 genes, copy number 5: ACTG1P13, AC107297.1, AC078828.1, AC107029.1, AC107029.2, COL8A1, AC069222.1, CMSS1, FILIP1L, MIR3921, AC129803.1, TMEM30CP, DUSP12P1, VTI1BP1, TBC1D23, NIT2, TOMM70, LNP1, TMEM45A, ADGRG7, AC069223.1, GMFBP1, TFG.
- chr3:123,490,820–125,916,384, 53 genes, copy number 5 (within-gene range 4–5): HACD2, MYLK-AS1, MYLK, MYLK-AS2, AC020634.2, AC020634.1, CCDC14, ROPN1, KALRN, MIR5002, RPL7P15, MIR6083, RNU6-143P, AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK, ENO1P3, MUC13, HEG1, RNA5SP137, SLC12A8, RNU6-230P, MIR5092, ZNF148, DUTP1, DNAJB6P7, RNU6-232P, SNX4, Y_RNA, Y_RNA, OSBPL11, AF186996.3, AF186996.2, OR7E130P, OR7E29P, OR7E93P, OR7E53P, OR7E97P, AF186996.1, AC092902.4, AC092902.2, AC092902.1, MIR548I1, RPS3AP14, SNRPCP11, LINC02614, ENPP7P4, AC092903.2.
- chr3:151,085,697–152,496,813, 27 genes, copy number 5: MED12L, RNA5SP145, GPR171, P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1.
- chr3:169,003,022–171,938,715, 62 genes, copy number 5 (broad region; genes not listed).
- chr3:173,910,498–184,135,238, 167 genes, copy number 6–22 (within-gene range 3–22) (broad region; genes not listed).
- chr5:58,198–850,986, 31 genes, copy number 5–6 (within-gene range 4–6): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3.
- chr5:6,582,136–17,486,829, 178 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:54,933,699–55,211,628, 3 genes, copy number 5: AC006971.1, EGFR, EGFR-AS1.
- chr7:76,818,377–96,322,147, 236 genes, copy number 6–12 (within-gene range 3–12) (broad region; genes not listed).
- chr8:31,639,222–33,567,128, 24 genes, copy number 5: NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122.
- chr8:36,004,316–40,155,310, 99 genes, copy number 5 (broad region; genes not listed).
- chr9:102,515,204–102,657,514, 3 genes, copy number 5: AL442644.1, LINC00587, ZYG11AP1.
- chr10:5,154,140–5,632,566, 17 genes, copy number 5 (within-gene range 2–5): AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28, AL683826.1, UCN3, TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, LASTR.
- chr10:29,891,032–32,394,665, 55 genes, copy number 6: AL353093.1, JCAD, RNU6-598P, EEF1A1P39, AL353796.1, MTPAP, AL353796.2, DNM1P17, GOLGA2P6, RN7SL241P, MIR7162, NIFKP1, AL161651.1, CCND3P1, MAP3K8, HNRNPA1P32, AL590068.4, AL590068.1, RN7SL63P, AL590068.2, LYZL2, SVIL2P, LINC02644, ZNF438, AL359532.1, DDX10P1, AL359546.1, LINC02664, ZEB1-AS1, RNA5SP309, ZEB1, SPTLC1P1, AL117340.1, AL161935.1, AL161935.2, MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P.
- chr11:1,947,278–1,989,920, 2 genes, copy number 5–8: MRPL23, MRPL23-AS1.
- chr12:38,532,895–42,459,715, 45 genes, copy number 7–14 (within-gene range 4–14): AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1.
- chr14:99,737,693–99,965,378, 3 genes, copy number 6: EML1, RNU1-47P, VDAC3P1.
- chr15:20,835,372–20,866,314, 2 genes, copy number 5: POTEB2, RNU6-749P.
- chr15:21,102,843–21,167,357, 4 genes, copy number 6–7: RN7SL400P, AC126335.1, AC126335.2, BMS1P16.
- chr15:21,980,277–22,095,857, 8 genes, copy number 6 (within-gene range 2–13): OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2.
- chr15:22,125,511–22,152,897, 3 genes, copy number 5 (within-gene range 5–6): OR4N3P, AC010760.1, RPS8P10.
- chr15:46,099,193–50,182,817, 66 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).
- chr16:2,464,950–2,474,145, 2 genes, copy number 6 (within-gene range 4–6): AC106820.2, NTN3.
- chr16:27,787,528–33,707,213, 382 genes, copy number 5 (broad region; genes not listed).
- chr17:18,426,861–18,506,313, 8 genes, copy number 6–7: KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.
- chr18:23,453,287–25,818,532, 45 genes, copy number 5–8: RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P.
- chr19:55,600,022–55,624,566, 4 genes, copy number 5 (within-gene range 4–5): ZNF524, ZNF865, AC008735.4, ZNF784.
- chr20:87,250–1,657,779, 51 genes, copy number 5: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C, SIRPB2, AL049634.1, RNU6-917P, SIRPD, AL049634.2, SIRPB1, AL049634.3, SIRPG, SIRPG-AS1.
- chr20:30,294,550–30,403,384, 5 genes, copy number 5: AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1.
- chr21:8,759,077–8,880,976, 5 genes, copy number 5: LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1.
- chr21:43,414,483–43,479,534, 3 genes, copy number 7–89 (within-gene range 2–89): SIK1, LINC00319, LINC00313.
- chr21:44,172,169–44,194,338, 2 genes, copy number 8: AP001056.2, AP001056.1.
- chr22:15,282,557–15,644,330, 18 genes, copy number 6: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7.
- chr22:15,699,361–15,703,403, 2 genes, copy number 6 (within-gene range 2–6): POTEH-AS1, RNU6-816P.
- chr22:18,361,820–18,530,573, 10 genes, copy number 6–26: FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.
- chr22:18,605,355–18,615,900, 4 genes, copy number 11: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP.
- chr22:21,466,423–21,517,533, 2 genes, copy number 9: TMEM191C, PI4KAP2.

Autosomal genes at a single copy (total copy number 1): 3,922. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
